Gene-level copy-number profile of tumor specimen TCGA-J4-A67N-01A from TCGA case TCGA-J4-A67N, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.4 years (22,420 days).
Specimen TCGA-J4-A67N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.dc72ea3a-52eb-4722-b0aa-effa4544af8f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-J4-A67N-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1f83854c-d59e-49f9-9c9e-44a772e137cc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 7,895; copy number 2: 51,898.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-J4-A67N-01A-11D-A30D-01): tumor purity 0.74, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,693,124–7,845,177, 7 genes (within-gene range 0–1): AL359881.3, AL359881.2, AL359881.1, VAMP3, Z98884.2, PER3, Z98884.1.
- chr8:17,643,795–17,800,917, 1 gene (within-gene range 0–1): MTUS1.
- chr8:17,703,988–17,910,365, 6 genes (within-gene range 0–1): AC124069.1, RNA5SP256, AC027117.2, AC027117.1, FGL1, AC087273.1.
- chr10:87,817,928–88,584,530, 10 genes (within-gene range 0–1): CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,514. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
